Somatic mutation profile of cancer-model specimen HCM-CSHL-0625-C18-85M (3D Organoid, passage 7; aliquot HCM-CSHL-0625-C18-85M-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0625-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 66.6 years (24,332 days).
Specimen HCM-CSHL-0625-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aec8fe1-794f-4ad4-a656-abba026ee13f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0625-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0625-C18-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7981039-9df7-4295-82f6-837f13da8230

The open-access MAF lists 196 somatic variants for this specimen: 141 protein-altering or splice-affecting, 47 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 47, Nonsense Mutation 10, Intron 4, Frame Shift Del 2, 5'UTR 2, Splice Site 2, Splice Region 1, Frame Shift Ins 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.3079G>T p.E1027* | Nonsense Mutation (SNP) | VAF 445/448 reads (99%) | catalogued as rs1569153948, COSV100653229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 334/334 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AHCYL1 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 335/336 reads (100%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.687); catalogued as COSV63209218; called by muse, mutect2, varscan2
- APC | c.4480del p.E1494Kfs*13 | Frame Shift Del (DEL) | VAF 207/288 reads (72%) | catalogued as CD108356, COSV57321403, COSV57381675; called by mutect2, pindel, varscan2
- ATRX | c.4909G>T p.E1637* | Nonsense Mutation (SNP) | VAF 331/331 reads (100%) | catalogued as COSV64884492; called by muse, mutect2, varscan2
- CACNA1E | c.6856C>T p.R2286W (on ENST00000367573 / NM_001205293.3; = p.R2243W on NM_000721.4) | Missense Mutation (SNP) | VAF 424/853 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as rs762766720, COSV62391040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALD1 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 314/674 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375816775, COSV62645239; called by muse, mutect2, varscan2
- CD5L | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 386/785 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879069186, COSV100941033, COSV63821041; called by muse, mutect2, varscan2
- CH25H | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV64092286; called by muse, mutect2, varscan2
- CSMD2 | c.7367G>A p.R2456Q | Missense Mutation (SNP) | VAF 343/343 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs867709818, COSV53952924; called by muse, mutect2, varscan2
- DLEC1 | c.1790A>G p.Y597C | Missense Mutation (SNP) | VAF 364/557 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1393328329; called by muse, mutect2, varscan2
- EFS | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 548/1058 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778032789; called by muse, mutect2, varscan2
- EML5 | c.2846G>A p.G949E | Missense Mutation (SNP) | VAF 244/244 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV61350886; called by muse, varscan2
- FCN2 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 248/417 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1157947141; called by muse, varscan2
- FOXN4 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 133/484 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs958198313, COSV54492879; called by muse, varscan2
- FREM2 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 204/810 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61947552; called by muse, mutect2, varscan2
- GASK1B | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 210/211 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs138914646; called by muse, mutect2, varscan2
- GNAS | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 254/2406 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1568925561, COSV58327280; called by muse, mutect2, varscan2
- GPR50 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 570/570 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs900102278, COSV54440920, COSV99505940; called by muse, mutect2, varscan2
- GSC | c.759G>T p.L253F | Missense Mutation (SNP) | VAF 276/581 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.095); catalogued as COSV53077064, COSV53077706; called by muse, mutect2, varscan2
- GSN | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 143/492 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as rs556563870; ClinVar: benign; called by muse, mutect2, varscan2
- HDAC4 | c.981G>A p.T327= | Splice Region (SNP) | VAF 211/416 reads (51%) | catalogued as rs895364750, COSV61864965; called by muse, mutect2, varscan2
- HDX | c.1815G>T p.L605F | Missense Mutation (SNP) | VAF 98/98 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99946623; called by muse, mutect2, varscan2
- IGLV3-1 | c.123C>A p.C41* | Nonsense Mutation (SNP) | VAF 244/414 reads (59%) | catalogued as rs61731695; called by muse, mutect2, varscan2
- INPP4A | c.2257G>C p.A753P (on ENST00000074304 / NM_001134224.1; = p.A714P on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 366/737 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.269); catalogued as COSV50792793; called by muse, mutect2, varscan2
- IQSEC3 | c.1354G>A p.E452K (on ENST00000538872 / NM_001170738.2; = p.E149K on NM_015232.1) | Missense Mutation (SNP) | VAF 852/1380 reads (62%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1389676284; called by muse, mutect2
- KLHL32 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 343/503 reads (68%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs766818945, COSV65111992; called by muse, mutect2, varscan2
- KRAS | c.204G>T p.R68S | Missense Mutation (SNP) | VAF 186/620 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55640563, COSV55650115; called by muse, mutect2, varscan2
- KRT15 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 135/476 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs780820668; called by muse, mutect2, varscan2
- LAMA2 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 301/466 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752648056; called by muse, mutect2, varscan2
- LAYN | c.537G>T p.K179N (on ENST00000375615 / NM_001258390.1; = p.K171N on NM_178834.5) | Missense Mutation (SNP) | VAF 266/266 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65105162; called by muse, mutect2, varscan2
- LRRC66 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 201/641 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100602882; called by muse, mutect2, varscan2
- MANSC1 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 210/1056 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.068); catalogued as rs138511907; called by muse, mutect2, varscan2
- MAP1S | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 350/1010 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as rs376985455; called by muse, mutect2, varscan2
- MICALL2 | c.1051G>C p.A351P | Missense Mutation (SNP) | VAF 527/1047 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1408966509; called by muse, mutect2, varscan2
- MRAP | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 476/481 reads (99%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.269); catalogued as rs763168814; called by muse, mutect2, varscan2
- MROH2B | c.3247G>T p.D1083Y | Missense Mutation (SNP) | VAF 168/786 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV68189518; called by muse, mutect2, varscan2
- NCAM2 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 334/536 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.383); catalogued as COSV53105151; called by muse, mutect2, varscan2
- NDST1 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 208/906 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs746022379, COSV55790987; called by muse, mutect2, varscan2
- NFS1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 148/915 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs201504973; called by muse, mutect2, varscan2
- PAN3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 127/528 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs765586023, COSV56701201; called by muse, varscan2
- PAPPA2 | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 390/820 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs771214241, COSV62780032; called by muse, mutect2, varscan2
- PCARE | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 255/551 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100527680, COSV59053209; called by muse, mutect2, varscan2
- PCDHA1 | c.1649C>T p.T550M | Missense Mutation (SNP) | VAF 308/681 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.611); catalogued as rs1554118055, COSV65372632; called by muse, mutect2, varscan2
- PCDHA12 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 274/632 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV56542763; called by muse, varscan2
- PCDHB3 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 15/470 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1208055016, COSV50566047; called by muse, mutect2
- PCDHB3 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 314/694 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV50565386; called by muse, mutect2, varscan2
- PDZD2 | c.1609C>T p.R537* | Nonsense Mutation (SNP) | VAF 219/945 reads (23%) | catalogued as rs766389561, COSV56856603; called by muse, mutect2, varscan2
- PHLPP2 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 199/498 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.635); catalogued as rs746313254, COSV100673437; called by muse, mutect2, varscan2
- PIDD1 | c.2134C>T p.R712W | Missense Mutation (SNP) | VAF 333/695 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs769334697, COSV57192316; called by muse, mutect2, varscan2
- PLIN5 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 529/1051 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs751980899, COSV101113716; called by muse, mutect2, varscan2
- PRSS35 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 213/653 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs1367084252; called by muse, mutect2, varscan2
- R3HDML | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 268/1738 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs767349391; called by muse, varscan2
- REV3L | c.2094C>G p.N698K | Missense Mutation (SNP) | VAF 149/149 reads (100%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV62615617; called by muse, mutect2, varscan2
- RFTN2 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 426/865 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371736434; called by muse, mutect2, varscan2
- RYR2 | c.606C>A p.H202Q | Missense Mutation (SNP) | VAF 273/571 reads (48%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.613); catalogued as rs1438256315, COSV63691206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.7105G>A p.D2369N (on ENST00000389232; = p.D2370N on NM_001036.6) | Missense Mutation (SNP) | VAF 376/376 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754277171; called by muse, mutect2, varscan2
- SAMD9 | c.2557G>A p.V853I | Missense Mutation (SNP) | VAF 269/566 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs534758372, COSV101180317, COSV66078012; called by muse, mutect2, varscan2
- SEC14L5 | c.1714C>A p.Q572K | Missense Mutation (SNP) | VAF 411/837 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs902793015; called by muse, mutect2, varscan2
- SGK1 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 154/478 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs1041694995; called by muse, mutect2, varscan2
- SLC8A3 | c.889C>G p.L297V | Missense Mutation (SNP) | VAF 444/445 reads (100%) | SIFT tolerated (0.34); PolyPhen benign (0.175); catalogued as COSV63527685; called by muse, mutect2, varscan2
- SMAD4 | c.1048G>T p.V350F | Missense Mutation (SNP) | VAF 386/386 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61688949; called by muse, mutect2, varscan2
- SMAD6 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 522/523 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV56593281; called by muse, mutect2, varscan2
- SPG7 | c.2314G>A p.E772K (on ENST00000268704; = p.E779K on NM_003119.4) | Missense Mutation (SNP) | VAF 368/733 reads (50%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.502); catalogued as rs755429163; called by muse, mutect2, varscan2
- SRCIN1 | c.2564C>T p.T855M (on ENST00000621492; = p.T821M on NM_025248.3) | Missense Mutation (SNP) | VAF 184/592 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs568302959; called by muse, mutect2, varscan2
- SREBF2 | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 168/542 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs749042683; called by muse, mutect2, varscan2
- SSU72P3 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 418/1161 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1385805815; called by muse, mutect2, varscan2
- TG | c.6380G>A p.R2127Q | Missense Mutation (SNP) | VAF 291/445 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs749862463, COSV55070257; called by muse, mutect2, varscan2
- THBS2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 485/772 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759210002, COSV64677175; called by muse, mutect2, varscan2
- TMTC4 | c.60C>G p.F20L (on ENST00000376234 / NM_001350577.2; = p.F39L on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 472/669 reads (71%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV60893910; called by muse, mutect2, varscan2
- TNFAIP1 | c.75G>T p.L25F | Missense Mutation (SNP) | VAF 190/645 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.396); catalogued as COSV56877848; called by muse, mutect2, varscan2
- TNFSF14 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 468/1006 reads (47%) | catalogued as rs1314864954, COSV55591351; called by muse, mutect2, varscan2
- TRPS1 | c.2411C>T p.P804L (on ENST00000220888 / NM_001330599.2; = p.P817L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 182/603 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.998); catalogued as COSV55235159; called by muse, mutect2, varscan2
- ZIC3 | c.765G>T p.W255C | Missense Mutation (SNP) | VAF 519/520 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54975701; called by mutect2, varscan2
- ZNF208 | c.2828A>C p.K943T | Missense Mutation (SNP) | VAF 255/425 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV68100536; called by muse, mutect2, varscan2
- ZNF500 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 524/1045 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs991739831; called by muse, mutect2, varscan2
- ZNF506 | c.1248G>C p.K416N | Missense Mutation (SNP) | VAF 127/359 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV101475663; called by muse, mutect2, varscan2
- ZNF816 | c.194G>T p.S65I | Missense Mutation (SNP) | VAF 258/515 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1383822909; called by muse, mutect2, varscan2
- ZNFX1 | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 168/1042 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756545146, COSV65579719; called by muse, mutect2, varscan2
- ACP7 | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 297/643 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ADHFE1 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 104/365 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- AGBL4 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 281/281 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AKAP13 | c.1571C>G p.T524R | Missense Mutation (SNP) | VAF 596/598 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- AL358113.1 | c.343T>G p.L115V | Missense Mutation (SNP) | VAF 136/460 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.078); called by muse, mutect2
- BHLHE22 | c.641G>C p.G214A | Missense Mutation (SNP) | VAF 282/827 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, varscan2
- BTBD7 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 395/836 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C1QTNF1 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 125/434 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CAVIN2 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 312/690 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CD109 | c.1340T>G p.F447C | Missense Mutation (SNP) | VAF 79/279 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CFAP92 | c.435C>G p.F145L | Missense Mutation (SNP) | VAF 158/479 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLASRP | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 267/563 reads (47%) | called by muse, mutect2, varscan2
- DNAH1 | c.2001C>G p.S667R | Missense Mutation (SNP) | VAF 308/475 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPP10 | c.2063C>G p.S688C | Missense Mutation (SNP) | VAF 236/547 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- EDEM1 | c.1276T>G p.F426V | Missense Mutation (SNP) | VAF 308/462 reads (67%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EFCAB3 | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 327/483 reads (68%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF2B5 | c.1604G>T p.S535I (on ENST00000647909; = p.S527I on NM_003907.3) | Missense Mutation (SNP) | VAF 293/456 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- EPHA6 | c.1636G>C p.D546H | Missense Mutation (SNP) | VAF 303/456 reads (66%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ESS2 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 248/744 reads (33%) | called by muse, mutect2, varscan2
- FAM205C | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 394/621 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FBXO48 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 330/697 reads (47%) | called by muse, mutect2, varscan2
- FXR2 | c.1802C>G p.S601C | Missense Mutation (SNP) | VAF 427/427 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- GOLGA6L22 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 358/487 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- GRIK1 | c.2829G>T p.Q943H (on ENST00000327783 / NM_001330994.2; = p.Q899H on NM_175611.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 236/376 reads (63%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- H2AC11 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 536/538 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, varscan2
- HMGCR | c.393G>C p.L131F | Missense Mutation (SNP) | VAF 143/430 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IBTK | c.2524G>C p.D842H | Missense Mutation (SNP) | VAF 220/338 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- IGKV1-9 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 91/1035 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- INTS8 | c.2276C>T p.S759F | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- IPO11 | c.1597A>G p.I533V | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGA2 | c.944T>G p.L315* | Nonsense Mutation (SNP) | VAF 55/267 reads (21%) | called by muse, mutect2, varscan2
- ITGB4 | c.3223C>G p.Q1075E | Missense Mutation (SNP) | VAF 222/770 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2630G>T p.G877V | Missense Mutation (SNP) | VAF 297/298 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LECT2 | c.406dup p.H136Pfs*5 | Frame Shift Ins (INS) | VAF 127/358 reads (35%) | called by mutect2, pindel, varscan2
- LONRF2 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 239/397 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- LRP2 | c.1618A>T p.R540W | Missense Mutation (SNP) | VAF 396/766 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEP1A | c.1784-1G>C p.X595_splice | Splice Site (SNP) | VAF 90/300 reads (30%) | called by muse, mutect2, varscan2
- MINDY3 | c.94+1G>A p.X32_splice | Splice Site (SNP) | VAF 268/268 reads (100%) | called by muse, mutect2, varscan2
- MINK1 | c.3968C>A p.T1323N | Missense Mutation (SNP) | VAF 355/356 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- MSL1 | c.1072A>C p.T358P (on ENST00000398532 / NM_001365919.1; = p.T95P on NM_001012241.2) | Missense Mutation (SNP) | VAF 26/648 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2
- MYH13 | c.1708C>A p.P570T | Missense Mutation (SNP) | VAF 189/392 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MYH2 | c.4354C>G p.Q1452E | Missense Mutation (SNP) | VAF 255/255 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEU3 | c.954T>A p.S318R | Missense Mutation (SNP) | VAF 421/848 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NRG2 | c.585C>G p.I195M | Missense Mutation (SNP) | VAF 18/477 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2
- PHF8 | c.3159C>A p.H1053Q (on ENST00000357988 / NM_001184896.1; = p.H1017Q on NM_015107.3) | Missense Mutation (SNP) | VAF 133/381 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- POU4F3 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 254/1087 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PRSS53 | c.432C>A p.C144* | Nonsense Mutation (SNP) | VAF 42/1410 reads (3%) | called by muse, mutect2
- PTBP2 | c.319T>G p.L107V (on ENST00000426398 / NM_001300986.2; = p.L99V on NM_021190.4) | Missense Mutation (SNP) | VAF 79/156 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RALGAPA2 | c.4549G>A p.D1517N | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- STXBP1 | c.275A>T p.K92M | Missense Mutation (SNP) | VAF 140/556 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- TCOF1 | c.4132del p.S1378Pfs*197 (on ENST00000377797 / NM_001135243.1; = p.S1301Pfs*197 on NM_000356.4) | Frame Shift Del (DEL) | VAF 452/878 reads (51%) | called by pindel, varscan2
- TICAM1 | c.2006C>A p.A669E | Missense Mutation (SNP) | VAF 242/1085 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- TRAPPC12 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 526/527 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRIP6 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 326/643 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGGT1 | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 93/407 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- VEPH1 | c.1399G>C p.D467H | Missense Mutation (SNP) | VAF 158/515 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- WIZ | c.963C>A p.S321R | Missense Mutation (SNP) | VAF 227/768 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- XIRP2 | c.8897T>A p.L2966H (on ENST00000628543; = p.L3141H on NM_152381.6) | Missense Mutation (SNP) | VAF 421/844 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ZBTB41 | c.1729T>A p.C577S | Missense Mutation (SNP) | VAF 275/564 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF141 | c.686G>T p.C229F | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2
- ZNF793 | c.1058G>T p.C353F | Missense Mutation (SNP) | VAF 195/706 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804A | c.161A>G p.K54R | Missense Mutation (SNP) | VAF 251/569 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- A3GALT2 | c.495C>T p.R165= | Silent (SNP) | VAF 535/535 reads (100%) | called by muse, mutect2, varscan2
- ADCY5 | c.3165C>T p.R1055= | Silent (SNP) | VAF 367/529 reads (69%) | catalogued as rs752267672; called by muse, varscan2
- BEST2 | c.510G>A p.K170= | Silent (SNP) | VAF 347/565 reads (61%) | called by muse, mutect2, varscan2
- CCDC102B | c.921A>G p.P307= | Silent (SNP) | VAF 201/201 reads (100%) | called by muse, mutect2
- CDRT15L2 | c.279C>T p.Y93= | Silent (SNP) | VAF 226/353 reads (64%) | catalogued as rs1055329969; called by muse, mutect2, varscan2
- CSMD1 | c.10446C>T p.H3482= (on ENST00000520002; = p.H3481= on NM_033225.6) | Silent (SNP) | VAF 157/157 reads (100%) | catalogued as rs778517811; called by muse, mutect2, varscan2
- CTCFL | c.1932C>G p.V644= | Silent (SNP) | VAF 183/1258 reads (15%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.762C>A p.P254= | Silent (SNP) | VAF 685/685 reads (100%) | called by muse, mutect2
- DENND2B | c.621C>G p.P207= | Silent (SNP) | VAF 495/1045 reads (47%) | called by muse, mutect2, varscan2
- DGKD | c.2130C>T p.D710= (on ENST00000264057 / NM_152879.3; = p.D666= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 397/864 reads (46%) | catalogued as rs747461841, COSV51081587; called by muse, mutect2, varscan2
- DRD5 | c.855C>T p.R285= | Silent (SNP) | VAF 381/615 reads (62%) | catalogued as rs201697048, COSV58577368; called by muse, mutect2, varscan2
- ELOA2 | c.1080C>T p.S360= | Silent (SNP) | VAF 307/308 reads (100%) | catalogued as COSV55294848; called by muse, mutect2, varscan2
- EPHA2 | c.162G>C p.L54= | Silent (SNP) | VAF 118/262 reads (45%) | called by muse, mutect2, varscan2
- FANCF | c.405C>T p.R135= | Silent (SNP) | VAF 255/1027 reads (25%) | catalogued as rs1187828547; called by muse, mutect2, varscan2
- FKBP9 | c.1656G>A p.K552= | Silent (SNP) | VAF 320/814 reads (39%) | called by muse, varscan2
- FREM2 | c.4719C>A p.T1573= | Silent (SNP) | VAF 143/630 reads (23%) | called by muse, mutect2, varscan2
- H2AC11 | c.213C>T p.A71= | Silent (SNP) | VAF 544/545 reads (100%) | catalogued as rs773383414; called by muse, varscan2
- HHIPL1 | c.318G>A p.T106= | Silent (SNP) | VAF 453/907 reads (50%) | catalogued as rs541490286, COSV58092492; called by muse, mutect2, varscan2
- IL18 | c.393A>T p.T131= | Silent (SNP) | VAF 244/244 reads (100%) | called by muse, mutect2, varscan2
- ITGA4 | c.2757G>T p.L919= | Silent (SNP) | VAF 243/490 reads (50%) | called by muse, mutect2, varscan2
- KIAA1109 | c.13839A>G p.S4613= | Silent (SNP) | VAF 187/312 reads (60%) | catalogued as COSV52689788; called by muse, mutect2, varscan2
- KRTAP5-7 | c.420C>T p.C140= | Silent (SNP) | VAF 242/1081 reads (22%) | called by muse, mutect2, varscan2
- LDLRAD3 | c.966G>A p.G322= | Silent (SNP) | VAF 616/1278 reads (48%) | catalogued as rs750264934; called by muse, mutect2, varscan2
- MAGI1 | c.3603G>A p.L1201= (on ENST00000402939 / NM_001033057.2; = p.L1230= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 170/632 reads (27%) | called by muse, mutect2, varscan2
- NIPBL | c.4947A>G p.Q1649= | Silent (SNP) | VAF 125/530 reads (24%) | catalogued as rs1424683975; called by muse, mutect2, varscan2
- OR5D16 | c.789A>C p.V263= | Silent (SNP) | VAF 450/855 reads (53%) | catalogued as COSV65723099; called by muse, mutect2, varscan2
- PAX7 | c.1035C>T p.A345= | Silent (SNP) | VAF 663/664 reads (100%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1785C>T p.R595= | Silent (SNP) | VAF 194/437 reads (44%) | catalogued as COSV56496982; called by muse, varscan2
- PCDHGA12 | c.1560C>T p.F520= | Silent (SNP) | VAF 234/485 reads (48%) | catalogued as COSV52770644; called by muse, mutect2, varscan2
- PDE6B | c.1827G>A p.Q609= | Silent (SNP) | VAF 157/514 reads (31%) | catalogued as rs748138553; called by muse, mutect2, varscan2
- PER2 | c.3237C>T p.S1079= | Silent (SNP) | VAF 405/911 reads (44%) | catalogued as rs765956250, COSV54522379; called by muse, mutect2, varscan2
- PLXNB2 | c.2940C>G p.R980= | Silent (SNP) | VAF 240/782 reads (31%) | catalogued as rs189387400; called by muse, mutect2, varscan2
- PRKRA | c.699C>G p.L233= | Silent (SNP) | VAF 336/684 reads (49%) | called by muse, mutect2, varscan2
- RHOBTB2 | c.708C>T p.P236= | Silent (SNP) | VAF 316/316 reads (100%) | catalogued as COSV52570777; called by muse, mutect2, varscan2
- SCN7A | c.2115T>C p.C705= | Silent (SNP) | VAF 393/811 reads (48%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.2691G>T p.V897= | Silent (SNP) | VAF 391/888 reads (44%) | called by muse, mutect2, varscan2
- SLC1A6 | c.1530G>T p.L510= | Silent (SNP) | VAF 180/513 reads (35%) | catalogued as COSV99693884; called by muse, varscan2
- SLC22A13 | c.318G>A p.T106= | Silent (SNP) | VAF 221/672 reads (33%) | catalogued as rs753981089, COSV61291469; called by muse, mutect2, varscan2
- TRHR | c.849G>A p.R283= | Silent (SNP) | VAF 199/578 reads (34%) | called by muse, mutect2, varscan2
- TRPC6 | c.69G>A p.A23= | Silent (SNP) | VAF 566/566 reads (100%) | catalogued as rs895758434; called by muse, mutect2, varscan2
- TTN | c.13191C>A p.G4397= (on ENST00000591111; = p.G4351= on NM_003319.4) | Silent (SNP) | VAF 323/697 reads (46%) | called by muse, mutect2, varscan2
- TUBGCP2 | c.1149C>G p.A383= | Silent (SNP) | VAF 406/406 reads (100%) | catalogued as rs1344092595; called by muse, mutect2, varscan2
- VAT1L | c.450G>A p.P150= | Silent (SNP) | VAF 398/788 reads (51%) | catalogued as rs369885557; called by muse, mutect2, varscan2
- VCAN | c.9300C>T p.N3100= | Silent (SNP) | VAF 569/570 reads (100%) | catalogued as rs764970307, COSV54118279; called by muse, mutect2, varscan2
- ZBTB7A | c.297C>G p.V99= | Silent (SNP) | VAF 283/1082 reads (26%) | called by muse, mutect2, varscan2
- ZNF510 | c.945G>A p.G315= | Silent (SNP) | VAF 151/452 reads (33%) | catalogued as rs1280720745; called by muse, mutect2, varscan2
- ZNF517 | c.1153C>T p.L385= | Silent (SNP) | VAF 239/752 reads (32%) | called by muse, mutect2, varscan2
- CUL7 | c.-151C>T | 5'UTR (SNP) | VAF 296/854 reads (35%) | catalogued as rs940293699; called by muse, mutect2, varscan2
- IGFN1 | c.1242-66C>G | Intron (SNP) | VAF 516/1049 reads (49%) | called by mutect2, varscan2
- NGLY1 | c.1004-200A>T | Intron (SNP) | VAF 140/374 reads (37%) | called by muse, mutect2, varscan2
- NRG1 | chr8:31640273 C>T | 5'Flank (SNP) | VAF 128/427 reads (30%) | called by muse, varscan2
- S1PR3 | c.-217C>A | 5'UTR (SNP) | VAF 32/1034 reads (3%) | catalogued as rs1294839772; called by muse, mutect2
- TTN | c.34265-2965G>A | Intron (SNP) | VAF 113/266 reads (42%) | catalogued as rs1187512688, COSV100620439; called by muse, mutect2, varscan2
- UNC13B | c.761+6097C>T | Intron (SNP) | VAF 104/373 reads (28%) | called by muse, mutect2, varscan2
- ZFP14 | chr19:36331637 G>A | 3'Flank (SNP) | VAF 432/847 reads (51%) | called by muse, mutect2, varscan2
